Somatic mutation profile of tumor specimen TCGA-B5-A3F9-01A (aliquot TCGA-B5-A3F9-01A-21D-A228-09) from TCGA case TCGA-B5-A3F9, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 56.2 years (20,523 days).
Specimen TCGA-B5-A3F9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1db76fe7-b42d-4b0a-a6b1-3053f87784fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A3F9-10A (Blood Derived Normal), aliquot TCGA-B5-A3F9-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d62c807-a93c-4b9b-a305-041fd4330555

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 19, Frame Shift Del 3, Nonsense Mutation 3, Splice Site 2, RNA 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.12592C>T p.R4198* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as rs587783685, CM122102, COSV56409006, COSV56429446; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 7/57 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1690A>G p.N564D (on ENST00000521381 / NM_181523.3; = p.N294D on NM_181504.4) | Missense Mutation (SNP) | VAF 23/64 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.671); catalogued as rs1057519841, COSV57124003; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACOT12 | c.754A>G p.N252D | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100296966; called by muse, mutect2, varscan2
- AGO1 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV100940859; called by muse, mutect2
- AKAP8 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99511972; called by muse, mutect2, varscan2
- BZW1 | c.1078C>G p.Q360E | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.324); catalogued as COSV100729863; called by muse, mutect2
- CASP8 | c.201C>G p.F67L | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.542); catalogued as COSV51848446, COSV51860744, COSV99965421; called by muse, mutect2
- DNAH8 | c.8401C>T p.H2801Y | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100545785; called by muse, mutect2, varscan2
- ENO1 | c.452A>G p.N151S | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.083); catalogued as rs527568599, COSV52302874; called by muse, mutect2, varscan2
- FAT2 | c.1628G>A p.R543H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as rs778707746, COSV55829097; called by muse, mutect2, varscan2
- GLI2 | c.1442C>T p.T481M (on ENST00000361492 / NM_001374353.1; = p.T498M on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs894445064, COSV100083410; called by muse, mutect2, varscan2
- HIP1R | c.1093A>G p.M365V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV99458907; called by muse, mutect2, varscan2
- LAMB2 | c.4340C>T p.A1447V | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.734); catalogued as COSV100026240; called by muse, mutect2, varscan2
- LUC7L | c.899G>A p.R300Q | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated, low confidence (0.14); PolyPhen probably damaging (0.921); catalogued as rs1429219977, COSV53461108; called by muse, mutect2, varscan2
- MAGEA4 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 25/119 reads (21%) | catalogued as COSV52340262; called by muse, mutect2, varscan2
- METAP1 | c.985A>G p.M329V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56443958; called by muse, mutect2, varscan2
- MTG1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.353); catalogued as rs760217337, COSV53371315, COSV99529901; called by muse, mutect2, varscan2
- MYO15A | c.5945C>T p.A1982V | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs973099931, COSV99233177; called by muse, mutect2, varscan2
- NOL4 | c.916C>A p.L306M | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99306957; called by muse, mutect2
- NOS1 | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 9/97 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs772708191, COSV57607600; called by muse, mutect2
- OR4C46 | c.375C>A p.C125* | Nonsense Mutation (SNP) | VAF 32/158 reads (20%) | catalogued as COSV100060757; called by muse, mutect2, varscan2
- OR4Q3 | c.545A>G p.E182G | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.46); catalogued as COSV100057112; called by muse, mutect2
- OXCT1 | c.89del p.C30Ffs*18 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | catalogued as COSV52171229; called by mutect2, pindel, varscan2
- PCDHB8 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); catalogued as rs782378226, COSV50793440; called by muse, mutect2
- PCDHGA4 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV53919797; called by muse, mutect2
- PLEKHG5 | c.264C>A p.D88E (on ENST00000400915 / NM_001042663.3; = p.D51E on NM_020631.6) | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV100556889, COSV61703071; called by muse, mutect2
- PTEN | c.590del p.K197Rfs*2 | Frame Shift Del (DEL) | VAF 10/49 reads (20%) | catalogued as CM041824; called by mutect2, pindel, varscan2
- RERE | c.174C>G p.D58E | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.982); catalogued as COSV100556668; called by muse, mutect2, varscan2
- RETSAT | c.1256+1G>A p.X419_splice | Splice Site (SNP) | VAF 24/50 reads (48%) | catalogued as rs757469247, COSV99805779; called by muse, mutect2, varscan2
- SLC12A5 | c.2941G>A p.E981K (on ENST00000454036 / NM_001134771.2; = p.E958K on NM_020708.5) | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as rs1319450206, COSV99275684; called by muse, mutect2, varscan2
- TNPO2 | c.151G>A p.V51I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.78); PolyPhen benign (0.003); catalogued as COSV63509593; called by muse, mutect2
- TRA2B | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0.262); catalogued as rs897229129, COSV99373282; called by muse, mutect2, varscan2
- USP6 | c.929G>A p.R310H | Missense Mutation (SNP) | VAF 19/265 reads (7%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.009); catalogued as rs370385666; called by muse, mutect2
- UTP14C | c.2210G>A p.G737D | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV101584316; called by muse, mutect2
- VIM | c.445C>T p.L149F | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as rs1245849739, COSV99813138; called by muse, mutect2, varscan2
- ZNF587 | c.170G>C p.W57S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100299531; called by muse, mutect2
- NMUR2 | c.880G>T p.V294L | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); called by muse, mutect2
- PGR | c.2639_2646+6del p.X880_splice | Splice Site (DEL) | VAF 7/39 reads (18%) | called by mutect2, pindel, varscan2
- SHROOM3 | c.4646del p.P1549Lfs*29 | Frame Shift Del (DEL) | VAF 5/18 reads (28%) | called by mutect2, varscan2
- TLL2 | c.1474dup p.W492Lfs*19 | Frame Shift Ins (INS) | VAF 9/46 reads (20%) | called by mutect2, pindel, varscan2
- ABCB8 | c.1119C>T p.R373= (on ENST00000297504 / NM_001282291.2; = p.R356= on NM_007188.5) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs748330890, COSV52506526; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3399G>A p.S1133= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs540993813, COSV101001943; called by muse, mutect2, varscan2
- BRDT | c.1137A>G p.E379= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100746424; called by muse, mutect2, varscan2
- CELF4 | c.129G>C p.P43= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV100611709; called by muse, mutect2
- CENPE | c.4695A>G p.Q1565= | Silent (SNP) | VAF 11/99 reads (11%) | catalogued as COSV99478177; called by muse, mutect2
- CKM | c.882C>T p.G294= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as rs752715405, COSV53465669, COSV99488397; called by muse, mutect2, varscan2
- HELZ2 | c.2074C>T p.L692= (on ENST00000467148 / NM_001037335.2; = p.L123= on NM_033405.3) | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV100915614; called by muse, mutect2, varscan2
- KRTAP10-4 | c.141C>T p.C47= | Silent (SNP) | VAF 56/384 reads (15%) | catalogued as rs587669033, COSV100551832, COSV100554070; called by muse, mutect2
- LTBP2 | c.2283C>T p.S761= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs537908823, COSV100000449; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCM3AP | c.1620T>G p.L540= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV99387070; called by muse, mutect2, varscan2
- MYO18B | c.7077G>A p.P2359= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as rs370775470; called by muse, mutect2, varscan2
- NF1 | c.624G>A p.A208= | Silent (SNP) | VAF 14/85 reads (16%) | catalogued as rs370184932; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOD1 | c.2325C>T p.Y775= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs765168394, COSV99768167; called by muse, mutect2, varscan2
- PHIP | c.381G>A p.A127= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs376769294; called by muse, varscan2
- PNPLA6 | c.1701G>A p.A567= (on ENST00000414982 / NM_001166111.2; = p.A519= on NM_006702.5) | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV99653864; called by muse, mutect2, varscan2
- PORCN | c.855G>T p.T285= (on ENST00000326194 / NM_203475.3; = p.T274= on NM_022825.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100400456; called by muse, mutect2
- PSMB5 | c.726C>A p.G242= | Silent (SNP) | VAF 12/77 reads (16%) | catalogued as COSV100557367; called by muse, mutect2, varscan2
- PTPN7 | c.834G>A p.P278= (on ENST00000495688; = p.P317= on NM_002832.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs370063601; called by muse, mutect2, varscan2
- TSHZ3 | c.2937C>T p.N979= | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs548221685, COSV53676459; called by muse, mutect2, varscan2
- SSPOP | n.6247G>A | RNA (SNP) | VAF 18/61 reads (30%) | catalogued as rs564059539, COSV100022604; called by muse, mutect2, varscan2
- ZNF658B | n.1154T>G | RNA (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
